Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A5FP, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A5FP-01A (Primary Tumor).

Gross Description: There is a melanoma tumor on the broad base up to 3.5 in its diameter, 1.5 cm thick.

Microscopic Description: Malignant melanoma of the skin with superficial ulceration. Breslow tumor thickness is 8 mm.

Diagnosis Details: Tumor Features: Pigmented, Tumor Extent: More than 4 mm with or without ulceration, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, trunk

Tumor size: 0 x 1.5 x 3.5 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade:

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Breslow tumor thickness is 8 mm.

Comments: None

ICD-O-3

Melanoma, malignant NOS 8720/3

Path Site Skin, trunk C44.5

OSCF Site: Skin, NOS C44.9

9/19/13

Source: NCI Genomic Data Commons file ce1f9a95-903a-4cb3-b816-28bd3e222eeb (TCGA-EB-A5FP.2AE044E0-B794-48DB-9A3A-1E0D7CBE9301.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).